Somatic mutation profile of tumor specimen 0DDDTM from CCDI case PBBNTY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 4.1 years (1,513 days).
Specimen 0DDDTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96fd1c92-379f-46ef-a6ce-ea9292aa71c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDDTN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6187f4ad-d9e6-4ca5-9db8-2d7029b1ad6c

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 2, Nonsense Mutation 1, Intron 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP61 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs765880107, COSV55649261; called by muse, varscan2
- FCRL1 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 105/319 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369514044; called by muse, mutect2, varscan2
- GRM1 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51372162; called by muse, mutect2, varscan2
- JAG2 | c.1429-6G>A | Splice Region (SNP) | VAF 71/163 reads (44%) | catalogued as rs747717548; called by muse, mutect2, varscan2
- CLCF1 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EIF4G1 | c.2735C>A p.T912K (on ENST00000346169 / NM_198241.3; = p.T717K on NM_004953.5) | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PCLO | c.8740G>T p.E2914* | Nonsense Mutation (SNP) | VAF 130/379 reads (34%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4689G>C p.M1563I | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCEAL5 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by mutect2, varscan2
- CRLF2 | c.507C>T p.N169= | Silent (SNP) | VAF 123/497 reads (25%) | catalogued as rs746685278; called by muse, mutect2, varscan2
- LRP5 | c.*9G>A | 3'UTR (SNP) | VAF 39/124 reads (31%) | catalogued as rs371493435, COSV99592281; called by muse, mutect2, varscan2
- TERF2 | c.*82C>T | 3'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs879216080; called by muse, varscan2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, varscan2
